Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4639, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4639-01A (Primary Tumor).

Pathology Accession

Pathology Report

DIAGNOSIS

(A) 12TH RIB:

Unremarkable segment of rib (gross examination only).

(B) PERINEPHRIC FAT:

Mature adipose tissue, no tumor present.

(C) LEFT KIDNEY AND ADRENAL:

RENAL CELL CARCINOMA (7.7 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE (100% CLEAR CELLS),

FUHRMAN NUCLEAR GRADE 2, CONFINED TO THE KIDNEY. (SEE COMMENT)

Adrenal gland, no tumor present.

Margins of resection free of tumor.

TCGA - CJ - 4639

COMMENT

The renal cell carcinoma in the left kidney is confined to the kidney and does not invade into the renal vein, perinephric adipose tissue or renal sinus adipose tissue.

GROSS DESCRIPTION

(A) 12TH RIB, GROSS ONLY - A segment of bone (3.2 x 1.1 x 0.8 cm), which is grossly unremarkable.

(B) PERINEPHRIC FAT - A segment of adipose tissue (16.0 x 10.0 x 0.5 cm). No discrete lesion is identified. Representative sections are submitted in B1-B3.

(C) LEFT KIDNEY AND ADRENAL - A radical nephrectomy specimen (26.0 x 16.5 x 5.5 cm), including the adrenal gland (7.0 x 5.0 x 1.5 cm). The adrenal gland appears unremarkable.

A tan-yellow, focally gelatinous tumor (7.7 x 7.0 x 5.5 cm) is present in the lower pole of the kidney. The tumor does not appear to involve the renal vein or the renal sinus. It is confined by a capsule and the closest external surface is 0.3 cm away. The uninvolved renal parenchyma appears unremarkable.

INK CODE: Black - external surface close to the tumor.

SECTION CODE: C1, ureter, renal vein, renal artery margins; C2, representative sections of adrenal gland; C3-C4, sections of tumor and renal sinus; C5-C8, sections of tumor with closest perinephric fat surface; C9-C10, representative sections of tumor; C11-C12, representative sections of uninvolved kidney.

CLINICAL HISTORY

Left renal mass.

Source: NCI Genomic Data Commons file 950fe5a4-3ba8-40c1-8743-8505c3051bce (TCGA-CJ-4639.C483D023-0ADC-438F-8656-003DA108C5ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).